Gene-level copy-number profile of tumor specimen ALCH-AEL4-TTP1-A from ALCHEMIST case ALCH-AEL4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.1 years (24,862 days).
Specimen ALCH-AEL4-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b7b3e806-17b6-4da2-9267-c237fd77f2d9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEL4-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,753 have no estimate.
https://portal.gdc.cancer.gov/files/3f147d63-a1a2-4c19-83da-f66dad91e45c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 196; copy number 1: 18,953; copy number 2: 31,511; copy number 3: 7,296; copy number 4: 600; copy number 5: 232; copy number 6: 33; copy number 7: 2; copy number 9: 1; copy number 10: 1; copy number 11: 5; copy number 22: 4; copy number 23: 36.

Homozygous deletions (total copy number 0; autosomes only): 196 genes in 94 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:34,755,047–34,788,097, 4 genes (within-gene range 0–2): GJB5, GJB4, AL121988.1, GJB3.
- chr2:2,638,178–3,157,797, 7 genes: AC018685.2, AC011995.2, AC018685.1, AC011995.1, LINC01250, AC019118.2, AC019118.1.
- chr2:71,984,182–72,148,038, 2 genes: RPS20P10, CYP26B1.
- chr2:128,445,081–128,519,177, 2 genes: RNA5SP103, ISCA1P6.
- chr2:129,922,863–130,051,131, 14 genes (within-gene range 0–2): PLAC9P1, LINC01856, RPL22P7, RAB6C-AS1, RAB6C, AC079776.3, AC079776.4, AC079776.2, AC079776.1, ARHGAP42P2, FAR2P1, AC018865.2, KLF2P1, CYP4F27P.
- chr2:131,361,111–131,364,881, 2 genes: RAB6D, AC073869.3.
- chr8:41,271,048–41,277,003, 3 genes (within-gene range 0–1): MIR548AO, RPS29P2, AC104393.1.
- chr10:2,071,845–2,098,269, 3 genes: AL441943.1, MIR6072, RNU6-889P.
- chr10:100,666,695–100,829,944, 2 genes: Metazoa_SRP, PAX2.
- chr10:130,505,106–131,311,721, 4 genes: Y_RNA, MIR378C, TCERG1L, TCERG1L-AS1.
- chr11:70,705,167–70,872,368, 4 genes (within-gene range 0–1): Y_RNA, AP000590.1, SHANK2-AS3, MIR3664.
- chr11:125,258,626–125,277,657, 2 genes (within-gene range 0–1): AP001007.1, RNU6-321P.
- chr11:131,187,022–131,350,917, 4 genes: AP002856.3, AP002856.1, AP002856.4, AP002856.2.
- chr11:132,284,302–132,404,060, 2 genes (within-gene range 0–1): NTM-IT, AP000843.1.
- chr11:133,840,631–133,865,627, 2 genes: SPATA19, AP001979.1.
- chr12:137,411–182,399, 3 genes (within-gene range 0–1): AC026369.1, AC026369.2, AC007406.3.
- chr12:2,659,937–2,672,220, 2 genes (within-gene range 0–1): AC007618.1, CACNA1C-AS2.
- chr12:3,211,663–3,366,122, 3 genes (within-gene range 0–1): AC005912.1, AC005865.1, LINC02827.
- chr12:3,462,718–3,469,296, 2 genes (within-gene range 0–1): AC005908.2, AC005908.1.
- chr12:5,032,388–5,521,536, 8 genes: AC005906.1, KCNA5, LINC02443, AC006206.2, AC006206.1, AC007848.2, AC007848.1, NTF3.
- chr12:13,582,031–13,683,886, 2 genes (within-gene range 0–1): AC007535.1, RN7SKP162.
- chr12:52,644,558–52,680,407, 2 genes: KRT2, KRT1.
- chr12:108,129,288–108,282,235, 2 genes: WSCD2, AC009729.1.
- chr13:19,152,567–19,187,618, 4 genes: SMPD4P2, AL139327.3, TUBA3C, AL139327.1.
- chr13:111,588,201–112,052,138, 4 genes: AL359649.1, LINC02337, LINC00354, AL138691.1.
- chr15:87,859,751–88,271,066, 3 genes: NTRK3, MED28P6, NTRK3-AS1.
- chr16:71,080,866–71,114,000, 2 genes (within-gene range 0–2): AC138625.2, AC138625.1.
- chr17:5,772,234–6,207,269, 5 genes: AC007846.1, AC007846.2, WSCD1, AC104770.1, RNU6-1264P.
- chr17:33,529,787–33,541,339, 2 genes (within-gene range 0–1): AA06, AC011824.3.
- chr17:45,895,783–45,910,779, 2 genes (within-gene range 0–2): MAPT-IT1, CR936218.2.
- chr18:37,243,040–37,762,131, 6 genes (within-gene range 0–1): CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.
- chr19:18,531,613–18,544,077, 3 genes: AC005387.1, FKBP8, AC005387.2.
- chr19:22,609,606–22,623,971, 3 genes: RAD54L2P1, LINC01785, AC011467.2.
- chr19:22,708,834–22,743,410, 2 genes (within-gene range 0–1): AC024563.2, VN1R87P.
- chr19:30,228,290–30,713,538, 3 genes (within-gene range 0–3): ZNF536, AC011504.1, AC011478.1.
- chr19:31,588,040–31,595,720, 2 genes: AC011525.1, AC011525.2.
- chr19:32,102,088–32,106,544, 2 genes: LINC01782, AC011518.1.
- chr19:42,752,686–43,171,515, 11 genes (within-gene range 0–1): PSG8, CEACAMP6, PSG8-AS1, PSG10P, PSG1, PSG6, PSG7, CEACAMP7, AC004784.1, PSG11, CEACAMP8.
- chr19:43,278,933–43,331,430, 3 genes: CEACAMP11, CEACAMP4, AC005392.2.
- chr20:61,077,224–61,083,750, 2 genes: AL121910.1, LINC01718.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 314 genes in 80 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,702,379–1,745,992, 4 genes, copy number 5 (within-gene range 2–5): CDK11A, AL031282.2, AL031282.1, SLC35E2A.
- chr1:7,991,134–8,220,529, 8 genes, copy number 6: AL034417.4, ERRFI1, AL034417.2, AL034417.1, AL358876.1, LINC01714, RNU1-7P, AL358876.2.
- chr1:27,404,230–27,490,167, 2 genes, copy number 5: WASF2, FO393419.2.
- chr1:120,489,860–120,842,110, 5 genes, copy number 11 (within-gene range 4–11): AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26.
- chr1:154,376,966–154,406,564, 3 genes, copy number 5 (within-gene range 3–5): AL162591.1, RPSAP17, IL6R-AS1.
- chr1:180,509,380–180,566,523, 2 genes, copy number 6: OVAAL, Y_RNA.
- chr1:198,638,457–198,757,476, 3 genes, copy number 6: PTPRC, AL157402.2, PEBP1P3.
- chr1:206,634,196–206,684,419, 2 genes, copy number 5: DYRK3-AS1, DYRK3.
- chr1:206,897,443–207,144,972, 11 genes, copy number 5 (within-gene range 4–5): IL24, FCMR, AC098935.2, AC098935.1, PIGR, FCAMR, C1orf116, PFKFB2, YOD1, C4BPB, C4BPA.
- chr1:207,225,798–207,386,804, 3 genes, copy number 5: C4BPAP2, AL596218.1, CD55.
- chr4:25,472,517–25,506,675, 2 genes, copy number 5: AC133963.2, AC133963.1.
- chr4:40,423,267–40,630,875, 4 genes, copy number 5: RBM47, AC098869.2, AC098869.1, MIR4802.
- chr5:55,944,656–56,233,330, 9 genes, copy number 5: AC016596.2, AC008892.1, FLJ31104, AC016596.1, ANKRD55, RNU6-299P, RPL17P22, RNA5SP184, C1GALT1P2.
- chr5:91,223,419–91,612,566, 11 genes, copy number 5: AC093281.1, AC093281.2, RNU4-90P, AC123595.1, AC123595.2, Metazoa_SRP, AC008799.1, AC008799.2, ARRDC3, ARRDC3-AS1, RAB5CP2.
- chr5:95,701,249–95,961,851, 10 genes, copy number 5–6: AC008840.1, RHOBTB3, GLRX, HSPD1P11, GGCTP1, AC008592.3, LINC01554, AC008592.4, AC008592.1, ELL2.
- chr5:98,929,171–98,995,013, 3 genes, copy number 5: LINC02062, Y_RNA, AC022121.1.
- chr6:39,039,603–39,115,186, 4 genes, copy number 22: AL035690.1, GLP1R, SAYSD1, ANKRD18EP.
- chr6:41,405,819–42,693,505, 37 genes, copy number 10–23: AL136967.2, FOXP4-AS1, LINC01276, FOXP4, MIR4641, MDFI, NPM1P51, TFEB, AL035588.1, PGC, AL365205.4, FRS3, AL365205.1, PRICKLE4, TOMM6, USP49, AL365205.3, AL365205.2, AL160163.1, MED20, Y_RNA, BYSL, CCND3, RNU6-761P, AL513008.1, TAF8, AL512274.1, C6orf132, AL096814.1, AL096814.2, GUCA1A, GUCA1B, MRPS10, TRERF1, AL591473.1, UBR2, RNU6-890P.
- chr7:7,640,711–8,004,053, 4 genes, copy number 5 (within-gene range 3–5): UMAD1, AC007161.3, AC007161.2, AC007161.1.
- chr7:16,791,811–17,558,909, 14 genes, copy number 5: AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2, AC019117.1.
- chr7:30,134,986–30,367,689, 8 genes, copy number 5 (within-gene range 3–7): MTURN, AC007036.2, AC007036.3, RPS27P16, AC007036.1, ZNRF2, MIR550A1, MIR550B1.
- chr7:130,840,204–131,110,176, 9 genes, copy number 5 (within-gene range 3–5): AC016831.3, LINC00513, MIR29A, AC016831.1, MIR29B1, AC016831.4, AC058791.1, LINC-PINT, RNU6-1010P.
- chr12:40,156,113–40,224,915, 2 genes, copy number 5 (within-gene range 2–5): LINC02471, LRRK2-DT.
- chr12:108,621,895–108,642,349, 3 genes, copy number 5: SELPLG, AC007569.1, MIR4496.
- chr12:108,833,721–108,837,006, 2 genes, copy number 5: AC087893.2, MIR619.
- chr14:35,511,825–36,658,801, 31 genes, copy number 5–6 (within-gene range 4–6): KRT18P6, INSM2, RALGAPA1, AL137818.1, QRSL1P3, AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2, AL133304.3, AL133304.1, ILF2P2, AL133304.2, LINC00609, PTCSC3, AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1.
- chr14:39,114,223–39,388,513, 12 genes, copy number 5–6: GEMIN2, TRAPPC6B, AL109628.2, RPL7AP2, AL132639.3, PNN, AL132639.1, YTHDF2P1, MIA2, AL132639.2, GLRX5P3, COILP1.
- chr14:49,893,082–49,913,760, 3 genes, copy number 6: ARF6, RNU6-189P, Metazoa_SRP.
- chr14:55,559,072–55,701,526, 2 genes, copy number 5 (within-gene range 3–5): KTN1, Y_RNA.
- chr14:61,294,909–61,776,260, 9 genes, copy number 5 (within-gene range 2–7): AL359220.1, AL355916.3, AL355916.2, LINC01303, AL355916.1, HIF1A-AS1, HIF1A, HIF1A-AS3, AL137129.1.
- chr14:65,197,254–65,235,101, 2 genes, copy number 5: LINC02324, AL355076.3.
- chr14:67,819,779–68,730,218, 8 genes, copy number 5 (within-gene range 2–8): RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1, PPIAP6, AL121820.3.
- chr16:30,524,004–30,534,852, 3 genes, copy number 5 (within-gene range 3–5): ZNF768, AC002310.4, AC002310.5.
- chr17:8,140,472–8,190,180, 9 genes, copy number 5: PER1, MIR6883, AC129492.3, VAMP2, TMEM107, SNORD118, AC129492.4, BORCS6, AC129492.6.
- chr19:1,238,179–1,244,825, 2 genes, copy number 5: AC004221.1, ATP5F1D.
- chr19:2,071,036–2,099,593, 2 genes, copy number 5: MOB3A, IZUMO4.
- chr19:48,954,815–48,993,310, 4 genes, copy number 5: BAX, AC026803.2, FTL, GYS1.
- chr20:47,209,214–47,356,889, 4 genes, copy number 5: ZMYND8, AL031666.2, AL031666.3, AL031666.1.
- chr20:50,247,643–50,585,879, 10 genes, copy number 5–6: PELATON, LINC01270, LINC01271, RN7SL636P, COX6CP2, PTPN1, RN7SL672P, Y_RNA, AL133230.1, MIR645.
- chr20:53,552,770–53,668,758, 4 genes, copy number 5: AL157838.1, ZNF217, AC005808.1, RNU7-14P.

Autosomal genes at a single copy (total copy number 1): 18,215. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
